TARGET case TARGET-00-RO02496 — Acute Myeloid Leukemia (TARGET-AML)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/3cfc8812-a184-4a2b-8d70-fecf6a02b2f4

Biospecimens (1 sample)
- Sample TARGET-00-RO02496-14A: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.
